Somatic mutation profile of tumor specimen MP2PRT-PAPXIK-TMP1-A (aliquot MP2PRT-PAPXIK-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPXIK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.5 years (4,218 days).
Specimen MP2PRT-PAPXIK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b707fb9-5811-4ee8-9c93-b0b6e990d881.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPXIK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPXIK-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3449181-3d46-4920-8278-b6f9c8a1769b

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJB4 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 119/326 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.394); catalogued as rs185327282; called by muse, mutect2, varscan2
- ZBED9 | c.1439G>A p.R480Q | Missense Mutation (SNP) | VAF 117/517 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763539074, COSV71729253; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2624C>T p.S875F | Missense Mutation (SNP) | VAF 23/310 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA1I | c.5463C>T p.I1821= | Silent (SNP) | VAF 138/306 reads (45%) | catalogued as rs757162923; called by muse, mutect2, varscan2
- LRP1B | c.2598C>T p.G866= | Silent (SNP) | VAF 100/260 reads (38%) | catalogued as rs376088575; called by muse, mutect2, varscan2
